Gene-level copy-number profile of tumor specimen HCM-CSHL-0603-C18-06A from HCMI case HCM-CSHL-0603-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.7 years (25,459 days).
Specimen HCM-CSHL-0603-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 631c461b-430a-4634-9ebc-79eeb33d7be0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0603-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/2b2317d7-fb5f-4579-b480-31e7395fed3a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 1,451; copy number 2: 19,923; copy number 3: 25,072; copy number 4: 9,489; copy number 5: 795; copy number 6: 485; copy number 7: 1,487; copy number 8: 36; copy number 9: 24; copy number 10: 1; copy number 11: 52; copy number 12: 7; copy number 14: 48; copy number 15: 2; copy number 17: 5; copy number 18: 7.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr8:12,064,389–12,175,771, 8 genes (within-gene range 0–1): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, AC130366.1, USP17L7, USP17L2, FAM90A2P.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–2): ACOT1, NT5CP2.
- chr15:34,382,069–34,521,791, 6 genes (within-gene range 0–2): MIR1233-1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–2): MIR1233-2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,669 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:104,738,597–104,804,107, 1 gene, copy number 10 (within-gene range 4–10): LHFPL3-AS1.
- chr7:105,439,661–106,315,743, 16 genes, copy number 7–11: PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2.
- chr7:114,922,359–115,019,202, 1 gene, copy number 11: MDFIC.
- chr7:116,524,994–117,715,971, 40 genes, copy number 8–17 (within-gene range 4–17): CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr7:133,253,073–134,066,589, 1 gene, copy number 15 (within-gene range 4–15): EXOC4.
- chr7:133,315,009–133,315,413, 1 gene, copy number 15: AC083875.1.
- chr7:158,590,629–159,233,377, 11 genes, copy number 7: LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:47,202,444–140,638,283, 1,276 genes, copy number 7 (broad region; genes not listed).
- chr13:26,755,200–33,676,796, 127 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:18,450,244–18,494,945, 5 genes, copy number 7 (within-gene range 7–8): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.
- chr20:21,705,659–23,086,324, 24 genes, copy number 7: PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93.
- chr20:31,257,664–33,181,412, 78 genes, copy number 8–18 (broad region; genes not listed).
- chr20:33,912,323–36,088,192, 88 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
